Somatic mutation profile of tumor specimen TCGA-VT-A80J-01A (aliquot TCGA-VT-A80J-01A-11D-A36J-09) from TCGA case TCGA-VT-A80J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.1 years (17,925 days).
Specimen TCGA-VT-A80J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ce3424-6cc5-4a11-8b8b-fc90bf475621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VT-A80J-11A (Solid Tissue Normal), aliquot TCGA-VT-A80J-11A-22D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c379cdc-0d16-44a7-aa81-2d7b546a279d

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.537T>G p.H179Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACCS | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV99772642; called by muse, mutect2, varscan2
- AHNAK2 | c.8329T>C p.S2777P | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564635013, COSV100315553; called by muse, mutect2, varscan2
- ANG | c.386T>A p.V129D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100390815; called by muse, mutect2, varscan2
- APLNR | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV57244270; called by muse, varscan2
- BEGAIN | c.1631C>A p.S544Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100766904; called by muse, mutect2
- CARD6 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54566214; called by muse, mutect2
- CDH26 | c.2188C>G p.P730A (on ENST00000348616 / NM_177980.4; = p.P63A on NM_021810.6) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.083); catalogued as COSV99721781; called by muse, mutect2, varscan2
- CLDN6 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58510316; called by muse, mutect2, varscan2
- CPS1 | c.4203C>A p.N1401K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV99242156; called by muse, mutect2, varscan2
- CTDP1 | c.2795G>T p.S932I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99310108; called by muse, mutect2, varscan2
- ECM1 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | catalogued as COSV100681630; called by muse, mutect2, varscan2
- FAM210B | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV100452761, COSV57168039; called by muse, mutect2
- GINS1 | c.448-2A>G p.X150_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99319948; called by muse, mutect2, varscan2
- KHDRBS1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as COSV100306100; called by muse, mutect2
- LAMB2 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100025891; called by muse, mutect2
- LIN37 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99137377; called by muse, mutect2, varscan2
- LRIT2 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258399; called by mutect2, varscan2
- MAGED1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as COSV100431378; called by muse, mutect2, varscan2
- MYL1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100751498; called by muse, mutect2, varscan2
- MYO5C | c.3544C>T p.H1182Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV55902509; called by muse, mutect2, varscan2
- NPFFR2 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV100440299, COSV100440960; called by muse, mutect2
- PRAMEF14 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1283917666; called by muse, mutect2, varscan2
- RAI1 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99883330; called by muse, mutect2, varscan2
- SASH1 | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772766127, COSV100820894; called by muse, mutect2, varscan2
- SCGN | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200726171; called by mutect2, varscan2
- SHANK1 | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs927786260, COSV99520181; called by muse, mutect2, varscan2
- SPANXD | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65152939, COSV65153044; called by muse, mutect2, varscan2
- TM2D1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV99623333; called by muse, mutect2, varscan2
- UBXN4 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99738657; called by muse, mutect2
- ZFAT | c.3559G>A p.V1187M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs915080825, COSV64742746; called by muse, mutect2
- ADCY8 | c.681C>T p.C227= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53904553; called by muse, mutect2, varscan2
- BTBD2 | c.906G>A p.T302= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs763587966, COSV99724512; called by muse, mutect2, varscan2
- DLGAP2 | c.300T>C p.G100= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101421019; called by muse, mutect2
- EPB41L1 | c.36G>A p.K12= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99148928; called by muse, varscan2
- FILIP1 | c.2217T>C p.D739= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99383851; called by muse, mutect2
- FLG2 | c.1896C>G p.G632= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV101165591, COSV66171895; called by muse, mutect2, varscan2
- HIPK4 | c.768C>T p.D256= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs377700394; called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>T p.S20= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs577917177; called by muse, mutect2
- MUC17 | c.3810C>A p.T1270= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV100071580, COSV60306270; called by muse, mutect2, varscan2
- MYH2 | c.4806C>T p.S1602= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99819253; called by muse, mutect2, varscan2
- NTRK3 | c.1500T>A p.T500= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100445870; called by muse, mutect2
- ZCCHC12 | c.813C>T p.D271= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1174068367, COSV59571255, COSV59572524; called by muse, mutect2, varscan2
- ZNHIT3 | c.93G>C p.S31= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- DOCK4 | c.2736+3931T>G | Intron (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
